Somatic mutation profile of tumor specimen TCGA-AG-A02N-01A (aliquot TCGA-AG-A02N-01A-11D-A183-10) from TCGA case TCGA-AG-A02N, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 67.6 years (24,687 days).
Specimen TCGA-AG-A02N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5ab596e4-9422-4429-91c5-5a8f15a0ed8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-A02N-11A (Solid Tissue Normal), aliquot TCGA-AG-A02N-11A-11W-A096-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b03cd6b-d9da-4c53-af33-4ecc3d20c344

The open-access MAF lists 1,407 somatic variants for this specimen: 1,056 protein-altering or splice-affecting, 333 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 737, Silent 333, Frame Shift Del 175, Nonsense Mutation 63, Frame Shift Ins 37, In Frame Del 15, Splice Site 15, Intron 12, Splice Region 12, 3'Flank 3, Translation Start Site 2, 3'UTR 2.

Variants (750 of 1,407; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.3460C>T p.R1154W | Missense Mutation (SNP) | VAF 87/161 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs387907208, CM124860, COSV53963892; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.694C>T p.R232* | Nonsense Mutation (SNP) | VAF 97/240 reads (40%) | hotspot (GDC flag); catalogued as rs397515734, CM920029, COSV57320753; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 89/247 reads (36%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CACNA1A | c.3423del p.K1142Rfs*48 | Frame Shift Del (DEL) | VAF 147/394 reads (37%) | catalogued as rs746790849; ClinVar: pathogenic; called by mutect2, varscan2
- CARD11 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 96/216 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.432); catalogued as rs577877958, COSV101211076, COSV67802724; called by muse, mutect2, varscan2
- CFTR | c.3472C>T p.R1158* | Nonsense Mutation (SNP) | VAF 87/182 reads (48%) | catalogued as rs79850223, CM920180, COSV50107726; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 46/187 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 66/142 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KCNH2 | c.453dup p.T152Hfs*180 | Frame Shift Ins (INS) | VAF 18/50 reads (36%) | catalogued as rs761863251; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 49/94 reads (52%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.5476C>T p.R1826* | Nonsense Mutation (SNP) | VAF 29/57 reads (51%) | catalogued as rs747349942, CM983961, COSV70356540; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LARS2 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs770440975, COSV55530962; ClinVar: likely pathogenic; called by muse, varscan2
- MLH1 | c.1459C>T p.R487* | Nonsense Mutation (SNP) | VAF 131/168 reads (78%) | catalogued as rs63749795, CM000177, COSV51615892; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MUTYH | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 114/305 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143353451, CM042753, COSV58344345; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NR2E3 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs527236086, CM1312695, COSV100489160, COSV58907132; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 81/211 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs786201057, CM102351, CM157948, COSV52667346, COSV52673504, COSV52688693, COSV99037266; ClinVar: likely pathogenic / pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TRPS1 | c.2686dup p.C896Lfs*42 (on ENST00000220888 / NM_001330599.2; = p.C909Lfs*42 on NM_014112.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 77/314 reads (25%) | catalogued as rs1554617582; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- VWF | c.6553C>T p.R2185W | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs569962285, COSV99777509; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ZBTB18 | c.556C>T p.R186* | Nonsense Mutation (SNP) | VAF 13/122 reads (11%) | catalogued as rs1064792999, CM162492, COSV62396102; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AACS | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 50/81 reads (62%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs200966429, COSV99907600; called by muse, mutect2, varscan2
- AADACL4 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0.094); catalogued as rs775507000, COSV66105905; called by muse, mutect2, varscan2
- ABCA1 | c.3187G>A p.V1063M | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101036278; called by muse, mutect2, varscan2
- ABCA9 | c.4130T>C p.L1377P | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs137862082; called by muse, mutect2, varscan2
- ABCC6 | c.3956C>T p.A1319V | Missense Mutation (SNP) | VAF 41/86 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.948); catalogued as rs1326218777, COSV99227808; called by muse, mutect2, varscan2
- ABCC6 | c.1250T>C p.V417A | Missense Mutation (SNP) | VAF 75/180 reads (42%) | SIFT tolerated (1); PolyPhen possibly damaging (0.509); catalogued as COSV99227812; called by muse, mutect2, varscan2
- ABCC9 | c.2199-1G>A p.X733_splice | Splice Site (SNP) | VAF 60/172 reads (35%) | catalogued as COSV99683828; called by muse, mutect2, varscan2
- ABHD5 | c.427G>T p.G143* | Nonsense Mutation (SNP) | VAF 107/259 reads (41%) | catalogued as COSV99185452; called by muse, mutect2, varscan2
- ABI3BP | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.183); catalogued as rs377450718; called by muse, mutect2, varscan2
- AC092143.1 | c.2323G>A p.A775T | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59248807; called by muse, mutect2, varscan2
- ACADVL | c.388_390del p.E130del | In Frame Del (DEL) | VAF 42/110 reads (38%) | catalogued as rs387906251; called by pindel, varscan2
- ACBD4 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs748121568, COSV58853173; called by muse, mutect2, varscan2
- ACSM5 | c.624-1G>T p.X208_splice | Splice Site (SNP) | VAF 23/57 reads (40%) | catalogued as COSV100088188, COSV100089757; called by muse, mutect2, varscan2
- ACTN1 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 59/138 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs765149759, COSV99516943; called by muse, mutect2, varscan2
- ADAMTS14 | c.3026G>T p.R1009M | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV100941202; called by muse, mutect2, varscan2
- ADAMTS14 | c.3478C>A p.P1160T | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as COSV64601013; called by muse, mutect2, varscan2
- ADAMTS18 | c.736C>T p.R246* | Nonsense Mutation (SNP) | VAF 57/130 reads (44%) | catalogued as COSV99270713; called by muse, mutect2, varscan2
- ADAMTS2 | c.3398G>A p.R1133Q | Missense Mutation (SNP) | VAF 170/382 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761111411, COSV52397039, COSV99283778; called by muse, mutect2, varscan2
- ADCY1 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 97/276 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.068); catalogued as COSV52030015, COSV99810988; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.100T>C p.C34R | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100416045; called by muse, mutect2, varscan2
- ADD2 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 72/211 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV100034287; called by muse, mutect2, varscan2
- ADGRA3 | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 192/578 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.658); catalogued as COSV99292722; called by muse, varscan2
- ADGRB3 | c.1276C>A p.Q426K | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV100999332; called by muse, mutect2, varscan2
- ADGRG6 | c.1217G>T p.R406M | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV51600896, COSV51601845; called by muse, mutect2, varscan2
- ADRB1 | c.638C>A p.P213H | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100992238; called by muse, mutect2, varscan2
- AFF1 | c.2406G>T p.R802S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as COSV57122430, COSV57123197; called by muse, mutect2
- AFMID | c.344C>T p.T115M | Missense Mutation (SNP) | VAF 124/279 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs771105807, COSV59975387; called by muse, mutect2, varscan2
- AGAP2 | c.3028G>A p.V1010M (on ENST00000547588 / NM_001122772.2; = p.V654M on NM_014770.4) | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); catalogued as COSV99221858; called by muse, mutect2, varscan2
- AGMAT | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.21); catalogued as rs199886325, COSV65435821; called by muse, mutect2, varscan2
- AGPAT4 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100210698; called by muse, varscan2
- AHCYL1 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754117077, COSV100779280; called by muse, mutect2, varscan2
- AHI1 | c.3223G>A p.G1075R | Missense Mutation (SNP) | VAF 165/405 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.81); catalogued as rs750115460, COSV99661636; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AHNAK2 | c.16544C>T p.S5515L | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs757019628, COSV60927512; called by muse, mutect2, varscan2
- AHR | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54121955; called by muse, mutect2, varscan2
- AK8 | c.36del p.E13Rfs*14 | Frame Shift Del (DEL) | VAF 59/169 reads (35%) | catalogued as rs757477831; called by mutect2, pindel, varscan2
- AKAP6 | c.2806C>T p.Q936* | Nonsense Mutation (SNP) | VAF 112/282 reads (40%) | catalogued as COSV99797087; called by muse, mutect2, varscan2
- AKAP9 | c.6976A>G p.T2326A (on ENST00000359028; = p.T2302A on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV100661730; called by muse, mutect2, varscan2
- AL592490.1 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV69427556; called by muse, mutect2, varscan2
- ALAD | c.626G>A p.R209Q | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201127458, COSV52958654; called by muse, mutect2, varscan2
- ALAS1 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 67/139 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867595113, COSV59629106; called by muse, mutect2, varscan2
- ALDH1B1 | c.1180C>T p.R394C | Missense Mutation (SNP) | VAF 160/413 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs201118307, COSV100890871; called by muse, mutect2, varscan2
- ALDH2 | c.864del p.K289Rfs*122 | Frame Shift Del (DEL) | VAF 170/362 reads (47%) | catalogued as rs771889973, COSV55672572; called by mutect2, pindel
- ALDH7A1 | c.673C>T p.L225F | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs752533662, COSV101301971; called by muse, mutect2, varscan2
- ALPK2 | c.4327C>A p.H1443N | Missense Mutation (SNP) | VAF 69/167 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV100863856; called by muse, mutect2, varscan2
- AMHR2 | c.800del p.G267Vfs*25 | Frame Shift Del (DEL) | VAF 27/95 reads (28%) | catalogued as rs748387033; called by mutect2, pindel, varscan2
- AMPH | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 105/252 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs151055033; called by muse, mutect2, varscan2
- ANGEL2 | c.364T>C p.S122P | Missense Mutation (SNP) | VAF 98/231 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100853896; called by muse, mutect2, varscan2
- ANK2 | c.5413C>T p.P1805S | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV99998633; called by muse, mutect2, varscan2
- ANKMY2 | c.654G>T p.L218F | Missense Mutation (SNP) | VAF 85/231 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as COSV100186748; called by muse, varscan2
- ANKRD30A | c.904del p.T302Hfs*95 (on ENST00000611781; = p.T246Hfs*95 on NM_052997.2) | Frame Shift Del (DEL) | VAF 19/57 reads (33%) | catalogued as rs755336380, COSV64619176; called by mutect2, pindel, varscan2
- ANKRD50 | c.3521G>A p.R1174Q | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.15); catalogued as rs753523756, COSV72385614; called by muse, mutect2, varscan2
- ANO1 | c.2349C>T p.I783= | Splice Region (SNP) | VAF 34/118 reads (29%) | catalogued as rs748584110, COSV62449147; called by muse, mutect2, varscan2
- ANTXR1 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 69/157 reads (44%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.998); catalogued as rs778487700, COSV58010465, COSV58020941; called by muse, mutect2, varscan2
- AP002748.5 | c.1590G>T p.Q530H | Missense Mutation (SNP) | VAF 138/312 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as COSV100567582; called by muse, mutect2, varscan2
- AP2A2 | c.2006del p.P669Lfs*67 | Frame Shift Del (DEL) | VAF 10/20 reads (50%) | catalogued as rs770443312, COSV59961800; called by mutect2, varscan2
- APOB | c.1062G>T p.E354D | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.73); PolyPhen benign (0.015); catalogued as COSV99262659; called by muse, varscan2
- APOC1 | c.129_130del p.L44Gfs*15 | Frame Shift Del (DEL) | VAF 68/229 reads (30%) | catalogued as rs756665290; called by pindel, varscan2
- APP | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs200487832, COSV61001845; called by muse, mutect2
- AQP2 | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 32/90 reads (36%) | catalogued as rs781478659, CM972978, COSV52229898; called by muse, varscan2
- AQP8 | c.363del p.M122Cfs*10 | Frame Shift Del (DEL) | VAF 49/135 reads (36%) | catalogued as rs759782104; called by mutect2, pindel, varscan2
- ARAP3 | c.4292G>T p.W1431L | Missense Mutation (SNP) | VAF 82/213 reads (38%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.007); catalogued as COSV99499151; called by muse, mutect2, varscan2
- ARHGAP17 | c.2440del p.Q814Nfs*23 (on ENST00000289968 / NM_001006634.3; = p.Q736Nfs*23 on NM_018054.6) | Frame Shift Del (DEL) | VAF 198/488 reads (41%) | catalogued as rs773922861; called by mutect2, varscan2
- ARHGAP32 | c.4597C>T p.R1533C (on ENST00000310343 / NM_001378025.1; = p.R1184C on NM_014715.4) | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs142674734; called by muse, varscan2
- ARHGAP9 | c.1235A>C p.E412A | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99953499; called by muse, mutect2, varscan2
- ARHGEF2 | c.1798A>T p.K600* (on ENST00000361247 / NM_001162383.2; = p.K572* on NM_004723.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 11/109 reads (10%) | catalogued as COSV100559825; called by muse, mutect2, varscan2
- ARHGEF2 | c.1797G>T p.Q599H (on ENST00000361247 / NM_001162383.2; = p.Q571H on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV100559827; called by muse, mutect2, varscan2
- ARID5B | c.2939A>G p.H980R | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.006); catalogued as rs759982287, COSV99688704; called by muse, mutect2, varscan2
- ARRDC2 | c.341del p.P114Rfs*4 | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | catalogued as rs767241138; called by pindel, varscan2
- ASH1L | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 132/366 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.006); catalogued as rs1416735817, COSV64207287; called by muse, mutect2, varscan2
- ASL | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs796051931, COSV100508752; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASPM | c.3863G>A p.R1288H | Missense Mutation (SNP) | VAF 108/279 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.019); catalogued as rs1227283442, COSV99659125; called by muse, varscan2
- ATAD2B | c.1404del p.F468Lfs*9 | Frame Shift Del (DEL) | VAF 96/262 reads (37%) | catalogued as rs866490133; called by mutect2, pindel, varscan2
- ATAD3B | c.593G>A p.S198N (on ENST00000308647; = p.S304N on NM_031921.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 185/459 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV100426227; called by muse, mutect2, varscan2
- ATG2A | c.1363T>C p.F455L | Missense Mutation (SNP) | VAF 70/172 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV101033658; called by muse, mutect2, varscan2
- ATG9A | c.1441C>A p.L481M | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs190418139, COSV99521330; called by muse, mutect2, varscan2
- ATP2A2 | c.3077T>C p.V1026A | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV100428272; called by muse, mutect2, varscan2
- ATP4A | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 65/172 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV52868670; called by muse, mutect2, varscan2
- ATP5F1A | c.917A>G p.H306R | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99958662; called by muse, mutect2, varscan2
- ATP8B4 | c.956C>T p.S319F | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.021); catalogued as COSV99462645; called by muse, mutect2, varscan2
- ATXN1 | c.1483G>A p.G495S | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.999); catalogued as rs757447543, COSV55208512; called by muse, mutect2, varscan2
- ATXN2L | c.2997del p.Q1002Kfs*50 | Frame Shift Del (DEL) | VAF 31/85 reads (36%) | catalogued as rs1288664341; called by mutect2, pindel, varscan2
- AVL9 | c.541C>T p.R181* | Nonsense Mutation (SNP) | VAF 50/117 reads (43%) | catalogued as rs149731136; called by muse, mutect2, varscan2
- B4GALNT1 | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 92/156 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.875); catalogued as rs765536804, COSV57542116; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BACH2 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57591356, COSV57611564; called by muse, mutect2, varscan2
- BAHD1 | c.677C>A p.P226H | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as COSV101346700; called by muse, mutect2, varscan2
- BCAM | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV99538393; called by muse, mutect2, varscan2
- BCAR3 | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.533); catalogued as COSV99549951; called by muse, mutect2, varscan2
- BCKDK | c.251G>A p.G84D | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.666); catalogued as COSV54891517; called by muse, mutect2, varscan2
- BCL6 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0.165); catalogued as rs767642014, COSV51655892; called by muse, mutect2, varscan2
- BCL9L | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.451); catalogued as rs762366458, COSV100599349; called by muse, mutect2
- BCR | c.2176C>T p.R726C | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1410579779, COSV100005713; called by muse, mutect2, varscan2
- BGN | c.377T>A p.I126N | Missense Mutation (SNP) | VAF 40/52 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100525041; called by muse, mutect2, varscan2
- BIRC3 | c.1343G>A p.R448Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.097); catalogued as rs759842920, COSV99679557; called by muse, varscan2
- BIRC3 | c.1463C>T p.T488M | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs200008391, COSV54816536; called by muse, varscan2
- BIRC6 | c.7420C>A p.L2474M | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.956); catalogued as COSV70204454; called by muse, mutect2
- BLCAP | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 103/222 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99289914; called by muse, mutect2, varscan2
- BMP7 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1247818896, COSV101215231; called by muse, mutect2, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 40/92 reads (43%) | catalogued as rs749043197; called by mutect2, varscan2
- BRINP2 | c.13T>A p.C5S | Missense Mutation (SNP) | VAF 105/453 reads (23%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV100837768; called by muse, mutect2, varscan2
- BTBD1 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99915098; called by muse, mutect2, varscan2
- BTBD10 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs767910760, COSV53398407; called by muse, mutect2, varscan2
- BTBD16 | c.1210T>C p.F404L | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99584381; called by muse, mutect2, varscan2
- C11orf49 | c.217del p.H73Tfs*24 | Frame Shift Del (DEL) | VAF 40/125 reads (32%) | catalogued as rs780813798; called by mutect2, pindel, varscan2
- C17orf64 | c.530T>C p.I177T | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV99293249; called by muse, mutect2, varscan2
- C17orf97 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 102/246 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.996); catalogued as rs373476599; called by muse, varscan2
- C19orf44 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.179); catalogued as rs1235224151, COSV99684821; called by muse, mutect2, varscan2
- C1S | c.1038G>T p.K346N | Missense Mutation (SNP) | VAF 57/252 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.091); catalogued as rs782476821, COSV100196247; called by muse, mutect2, varscan2
- C21orf91 | c.597dup p.E200Rfs*6 | Frame Shift Ins (INS) | VAF 125/235 reads (53%) | catalogued as rs1307648199; called by mutect2, pindel, varscan2
- C2CD2 | c.1028C>T p.A343V | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as rs746797812, COSV100297901; called by muse, mutect2, varscan2
- CABIN1 | c.4921C>T p.R1641* | Nonsense Mutation (SNP) | VAF 25/58 reads (43%) | catalogued as rs1279300604, COSV99572414; called by muse, mutect2, varscan2
- CACNB4 | c.659G>A p.R220H | Missense Mutation (SNP) | VAF 57/133 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1023200310, COSV52390628; called by muse, mutect2, varscan2
- CAD | c.398C>A p.S133Y | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV99254165; called by muse, mutect2, varscan2
- CAMP | c.365del p.G122Afs*65 (on ENST00000296435; = p.G119Afs*65 on NM_004345.5) | Frame Shift Del (DEL) | VAF 148/372 reads (40%) | catalogued as COSV56482061; called by mutect2, pindel, varscan2
- CAND2 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.043); catalogued as rs530014195, COSV99928312; called by muse, mutect2, varscan2
- CARMIL3 | c.1687A>G p.N563D | Missense Mutation (SNP) | VAF 68/174 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as COSV100549004; called by muse, mutect2, varscan2
- CAVIN4 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 56/144 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs375508129; called by muse, mutect2, varscan2
- CBLN3 | c.206del p.P69Lfs*35 | Frame Shift Del (DEL) | VAF 70/156 reads (45%) | catalogued as rs1268177561; called by mutect2, varscan2
- CBR4 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT tolerated (0.8); PolyPhen benign (0.129); catalogued as COSV100085724; called by muse, mutect2, varscan2
- CBX2 | c.496C>T p.R166* | Nonsense Mutation (SNP) | VAF 96/217 reads (44%) | catalogued as COSV99490678; called by muse, mutect2, varscan2
- CBX5 | c.85C>T p.R29C | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.662); catalogued as COSV52938713; called by muse, mutect2, varscan2
- CC2D2A | c.949G>A p.G317R | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs188018643, COSV67503016; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCAR1 | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 74/174 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs561113593, COSV99770340; called by muse, mutect2, varscan2
- CCDC106 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs374002589; called by muse, varscan2
- CCDC15 | c.581del p.K194Rfs*29 | Frame Shift Del (DEL) | VAF 34/105 reads (32%) | catalogued as rs759789184, COSV99049086; called by mutect2, varscan2
- CCDC191 | c.1457G>T p.S486I | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.424); catalogued as COSV99877784; called by muse, mutect2, varscan2
- CCNY | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 135/361 reads (37%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.931); catalogued as rs756155029, COSV99590029; called by muse, mutect2, varscan2
- CD163L1 | c.3139G>T p.G1047W | Missense Mutation (SNP) | VAF 85/126 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100549420; called by muse, mutect2, varscan2
- CD209 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 104/245 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs139712001; called by muse, mutect2, varscan2
- CD300E | c.457C>T p.R153* | Nonsense Mutation (SNP) | VAF 108/261 reads (41%) | catalogued as rs61748965; called by muse, mutect2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 52/234 reads (22%) | catalogued as rs781937995, COSV99163893; called by mutect2, pindel, varscan2
- CD93 | c.361del p.E121Rfs*79 | Frame Shift Del (DEL) | VAF 28/62 reads (45%) | catalogued as rs762805003; called by mutect2, pindel, varscan2
- CDCA2 | c.2461G>A p.V821I | Missense Mutation (SNP) | VAF 108/289 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV100398670; called by muse, mutect2, varscan2
- CDCA7L | c.1215del p.C406Vfs*46 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as COSV100181107; called by mutect2, pindel, varscan2
- CDH18 | c.1919A>G p.K640R | Missense Mutation (SNP) | VAF 27/52 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0.04); catalogued as COSV56953939; called by muse, mutect2, varscan2
- CDH19 | c.343T>G p.L115V | Missense Mutation (SNP) | VAF 89/193 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as rs768599786, COSV100050537; called by muse, mutect2, varscan2
- CDH2 | c.2152G>A p.A718T | Missense Mutation (SNP) | VAF 85/227 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as COSV99295035; called by muse, mutect2, varscan2
- CDH4 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs555725508, COSV64669075; called by muse, mutect2, varscan2
- CDH4 | c.1063T>G p.Y355D | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100848110; called by muse, mutect2, varscan2
- CDHR3 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.821); catalogued as rs776713785, COSV58420906; called by muse, mutect2, varscan2
- CDK12 | c.2921C>T p.P974L | Missense Mutation (SNP) | VAF 106/290 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1212731319, COSV101420215; called by muse, varscan2
- CEP104 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100986543; called by muse, mutect2, varscan2
- CEP170 | c.619G>C p.A207P | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100316128; called by muse, mutect2, varscan2
- CEP290 | c.5434_5435del p.E1812Kfs*5 | Frame Shift Del (DEL) | VAF 128/602 reads (21%) | catalogued as rs757609119; called by pindel, varscan2
- CEP57 | c.785del p.K262Rfs*31 | Frame Shift Del (DEL) | VAF 75/212 reads (35%) | catalogued as rs762013265, COSV57689966; called by mutect2, varscan2
- CEP97 | c.1855T>A p.F619I | Missense Mutation (SNP) | VAF 99/274 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1560022131, COSV59128381; called by muse, mutect2, varscan2
- CES5A | c.1279G>A p.G427S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs1288510111, COSV99306928; called by muse, mutect2, varscan2
- CETP | c.316G>A p.V106M | Missense Mutation (SNP) | VAF 81/190 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs371258270; ClinVar: benign; called by muse, mutect2, varscan2
- CFAP43 | c.4094T>G p.L1365W | Missense Mutation (SNP) | VAF 80/189 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100828972; called by muse, mutect2, varscan2
- CFAP44 | c.1669C>T p.R557W | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs113101974, COSV55611403; called by muse, mutect2, varscan2
- CFAP61 | c.2555C>T p.T852M | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.049); catalogued as COSV99842361; called by muse, mutect2, varscan2
- CFAP65 | c.1775del p.P592Lfs*8 | Frame Shift Del (DEL) | VAF 123/354 reads (35%) | catalogued as rs778664468; called by mutect2, pindel, varscan2
- CHD5 | c.4657G>A p.A1553T | Missense Mutation (SNP) | VAF 166/384 reads (43%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.045); catalogued as rs1160075084, COSV52420130; called by muse, mutect2
- CHD5 | c.2315C>T p.A772V | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs770153232, COSV52412970, COSV52414176; called by muse, mutect2, varscan2
- CHDH | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 60/120 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756480475, COSV59460051; called by muse, varscan2
- CHKA | c.525G>T p.E175D | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV99693825; called by muse, mutect2
- CHRD | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99200215; called by muse, mutect2, varscan2
- CHRNA3 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs76018802, COSV100467603; called by muse, varscan2
- CHRNA3 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.022); catalogued as rs777301381, COSV58776252; called by muse, varscan2
- CIRBP | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as COSV100309625; called by muse, mutect2, varscan2
- CIT | c.4540G>A p.A1514T | Missense Mutation (SNP) | VAF 77/163 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs751322516, COSV55859806, COSV99947919; called by muse, mutect2, varscan2
- CIT | c.3179G>A p.R1060Q | Missense Mutation (SNP) | VAF 148/272 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs781221253, COSV99947921; called by muse, mutect2, varscan2
- CLCN2 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 74/150 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs779315327, COSV99658070; called by muse, mutect2, varscan2
- CLCN4 | c.2183C>T p.T728M | Missense Mutation (SNP) | VAF 122/144 reads (85%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs483352716, COSV66466782; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- CLEC3A | c.395C>T p.P132L (on ENST00000651443; = p.P123L on NM_005752.6) | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as COSV100221995; called by muse, mutect2, varscan2
- CLEC4F | c.1754G>T p.W585L | Missense Mutation (SNP) | VAF 87/228 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV99713420; called by muse, mutect2, varscan2
- CLIC5 | c.1216C>T p.R406C (on ENST00000185206 / NM_001370649.1; = p.R247C on NM_016929.5) | Missense Mutation (SNP) | VAF 75/160 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs202022202, COSV51759804; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CLSTN1 | c.1841C>A p.P614H (on ENST00000377298 / NM_001009566.3; = p.P604H on NM_014944.4) | Missense Mutation (SNP) | VAF 111/257 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100790420; called by muse, mutect2, varscan2
- CMIP | c.845G>A p.R282Q (on ENST00000537098 / NM_198390.2; = p.R188Q on NM_030629.3) | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.945); catalogued as rs753543941, COSV101220805; called by muse, mutect2, varscan2
- CNDP2 | c.805G>A p.V269I | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs540790918, COSV60841893; called by muse, varscan2
- CNIH2 | c.153C>T p.R51= | Splice Region (SNP) | VAF 44/131 reads (34%) | catalogued as rs374304001; called by muse, mutect2, varscan2
- CNOT10 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100093721; called by muse, varscan2
- COG7 | c.865del p.A289Pfs*54 | Frame Shift Del (DEL) | VAF 46/134 reads (34%) | catalogued as rs1567340176; called by mutect2, pindel, varscan2
- COL17A1 | c.3778C>T p.R1260C | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770168630, COSV100792950; called by muse, mutect2, varscan2
- COL17A1 | c.2839C>A p.L947I | Missense Mutation (SNP) | VAF 84/184 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV100792952; called by muse, mutect2, varscan2
- COL4A2 | c.2414del p.P805Lfs*15 | Frame Shift Del (DEL) | VAF 32/94 reads (34%) | catalogued as rs1324194272; called by mutect2, pindel, varscan2
- COL5A2 | c.2137C>T p.R713* | Nonsense Mutation (SNP) | VAF 39/105 reads (37%) | catalogued as COSV100879847; called by muse, mutect2, varscan2
- CPEB3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 43/124 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.48); catalogued as COSV99798057; called by muse, mutect2, varscan2
- CPNE4 | c.1408G>A p.V470M | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1185355534, COSV70195985; called by muse, mutect2, varscan2
- CPSF1 | c.3157G>A p.E1053K | Missense Mutation (SNP) | VAF 102/165 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100450086; called by muse, mutect2, varscan2
- CPSF7 | c.232C>T p.R78C (on ENST00000394888 / NM_001136040.4; = p.R121C on NM_024811.4) | Missense Mutation (SNP) | VAF 147/386 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs1236908836, COSV100466853; called by muse, mutect2, varscan2
- CPXM2 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as rs200954130, COSV99580574; called by muse, mutect2, varscan2
- CPZ | c.1024C>T p.R342C (on ENST00000360986 / NM_001014447.3; = p.R331C on NM_003652.3) | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs755742622, COSV100248635; called by muse, mutect2
- CRACD | c.501del p.K167Nfs*82 | Frame Shift Del (DEL) | VAF 11/67 reads (16%) | catalogued as rs1180697484, COSV99950174; called by mutect2, pindel, varscan2
- CRADD | c.514G>A p.G172R | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1007288871, COSV60555931; called by muse, mutect2, varscan2
- CREBBP | c.7030C>T p.R2344W | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as rs1299672210, COSV52121347; called by muse, mutect2, varscan2
- CREBBP | c.2014C>T p.R672C | Missense Mutation (SNP) | VAF 112/299 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99062754; called by muse, mutect2, varscan2
- CRY1 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 64/237 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV99150255; called by muse, mutect2, varscan2
- CSMD3 | c.409G>T p.G137* | Nonsense Mutation (SNP) | VAF 91/138 reads (66%) | catalogued as COSV99819635; called by muse, varscan2
- CTNND2 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs774793947, COSV58874187; called by muse, mutect2, varscan2
- CTPS1 | c.1648C>T p.R550W | Missense Mutation (SNP) | VAF 70/171 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs552737439, COSV101009247; called by muse, varscan2
- CTSF | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs761039140, COSV59748000; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUL5 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 99/228 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs757736723, COSV67610534; called by muse, mutect2, varscan2
- CUL9 | c.6193G>A p.V2065I | Missense Mutation (SNP) | VAF 59/112 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs375119455, COSV52728976; called by muse, mutect2
- CYLC1 | c.1271del p.K424Rfs*69 | Frame Shift Del (DEL) | VAF 104/169 reads (62%) | catalogued as rs1385226543; called by mutect2, pindel, varscan2
- CYP11B1 | c.1489C>A p.L497I | Missense Mutation (SNP) | VAF 46/419 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.828); catalogued as COSV99454240; called by muse, mutect2, varscan2
- CYP1A1 | c.739T>C p.S247P | Missense Mutation (SNP) | VAF 81/201 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV101122187; called by muse, mutect2, varscan2
- CYP27C1 | c.1086del p.I364Sfs*14 | Frame Shift Del (DEL) | VAF 78/196 reads (40%) | catalogued as rs767024106; called by mutect2, varscan2
- CYP4F3 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 79/183 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs758905640, COSV99657600; called by muse, mutect2, varscan2
- CYP7B1 | c.662A>G p.D221G | Missense Mutation (SNP) | VAF 112/163 reads (69%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV100040356; called by muse, mutect2, varscan2
- DAO | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 48/84 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs566264618, COSV57323592; called by muse, mutect2, varscan2
- DAPK3 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1254949642, COSV100009408; called by muse, mutect2, varscan2
- DBNDD1 | c.55C>T p.P19S (on ENST00000002501 / NM_001042610.3; = p.P39S on NM_024043.3) | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.019); catalogued as COSV99136372; called by muse, mutect2, varscan2
- DCHS1 | c.8173G>A p.V2725M | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1564859204, COSV100197044; called by muse, varscan2
- DCLRE1C | c.1057G>A p.E353K (on ENST00000378278 / NM_001350965.2; = p.E238K on NM_022487.4) | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs541855040, COSV100739656; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCP2 | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV101203830; called by muse, mutect2, varscan2
- DDB1 | c.3004G>A p.E1002K | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV57101158; called by muse, mutect2, varscan2
- DDX11 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 148/293 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239984762, COSV99298710; called by muse, varscan2
- DDX23 | c.395A>G p.H132R | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs748440330, COSV57283663; called by muse, mutect2
- DDX50 | c.2056C>T p.R686* | Nonsense Mutation (SNP) | VAF 82/202 reads (41%) | catalogued as COSV101007156; called by muse, mutect2, varscan2
- DDX55 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 76/276 reads (28%) | catalogued as rs749112253, COSV99434051; called by muse, mutect2, varscan2
- DENND10 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 86/216 reads (40%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.866); catalogued as rs146864091; called by muse, mutect2, varscan2
- DENND3 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 56/340 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as rs773734634, COSV52805162, COSV99370069; called by muse, varscan2
- DGKK | c.1330C>T p.R444W | Missense Mutation (SNP) | VAF 67/95 reads (71%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.761); catalogued as rs782276961, COSV101052826; called by muse, mutect2, varscan2
- DGKZ | c.1246G>A p.E416K (on ENST00000454345 / NM_001105540.2; = p.E228K on NM_003646.4) | Missense Mutation (SNP) | VAF 68/133 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.832); catalogued as rs747019540, COSV58995647; called by muse, mutect2, varscan2
- DHX36 | c.766G>A p.A256T | Missense Mutation (SNP) | VAF 83/207 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as COSV100273145; called by muse, mutect2, varscan2
- DHX38 | c.1651G>A p.V551M | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs748565651, COSV99194171; called by muse, mutect2, varscan2
- DIS3 | c.2560T>C p.F854L | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as COSV100899816; called by muse, mutect2, varscan2
- DKK4 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 74/170 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.081); catalogued as rs772507402, COSV55182146; called by muse, varscan2
- DLC1 | c.4360G>A p.A1454T (on ENST00000276297 / NM_001348081.2; = p.A1017T on NM_006094.5) | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.376); catalogued as rs367679746; called by muse, mutect2, varscan2
- DLD | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.727); catalogued as rs201652869; called by muse, mutect2, varscan2
- DLGAP2 | c.1045G>A p.V349I | Missense Mutation (SNP) | VAF 92/220 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.389); catalogued as rs775940326, COSV70103218; called by muse, mutect2, varscan2
- DLGAP4 | c.1682C>T p.P561L | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs900115980, COSV59421170; called by muse, mutect2, varscan2
- DLL1 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 86/190 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1313716209, COSV64536606; called by muse, varscan2
- DLL4 | c.1870C>T p.R624W | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs754788022, COSV99989506; called by muse, mutect2, varscan2
- DMXL2 | c.2984C>A p.P995H | Missense Mutation (SNP) | VAF 62/143 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99195896; called by muse, mutect2, varscan2
- DNAH1 | c.6970G>A p.D2324N | Missense Mutation (SNP) | VAF 39/66 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs748004643, COSV70231803; called by muse, mutect2, varscan2
- DNAH2 | c.485C>T p.T162M | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.826); catalogued as rs759660250, COSV99317745; called by muse, mutect2, varscan2
- DNAH5 | c.12586C>A p.Q4196K | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99442784; called by muse, mutect2, varscan2
- DNAH7 | c.7001G>A p.R2334H | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs753046205, COSV100413102, COSV56751660; called by muse, mutect2, varscan2
- DNAJA3 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 105/279 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV52160527; called by muse, mutect2, varscan2
- DNAJC11 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 62/154 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV99601686; called by muse, varscan2
- DNER | c.451del p.R151Dfs*23 | Frame Shift Del (DEL) | VAF 63/163 reads (39%) | catalogued as COSV59159503; called by mutect2, pindel, varscan2
- DNMT1 | c.4103G>A p.R1368Q | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.832); catalogued as rs748486662, COSV100531474; called by muse, mutect2, varscan2
- DNMT1 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.084); catalogued as rs775139340, COSV100531475; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNMT3A | c.626G>A p.R209H | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.477); catalogued as rs1256370526, COSV53069137, COSV99264918; called by muse, mutect2, varscan2
- DOCK2 | c.4345C>T p.R1449C | Missense Mutation (SNP) | VAF 70/175 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs956858923, COSV99909293; called by muse, mutect2, varscan2
- DOCK6 | c.4054C>T p.R1352C | Missense Mutation (SNP) | VAF 77/153 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs550858597, COSV53912463; called by muse, mutect2, varscan2
- DOLK | c.1427C>T p.T476I | Missense Mutation (SNP) | VAF 85/200 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1387612676, COSV58279720; called by muse, mutect2, varscan2
- DPP8 | c.1477C>T p.R493* (on ENST00000341861 / NM_001320875.2; = p.R477* on NM_017743.6) | Nonsense Mutation (SNP) | VAF 51/113 reads (45%) | catalogued as COSV55681982; called by muse, mutect2, varscan2
- DRD5 | c.493T>C p.W165R | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58580173; called by muse, mutect2, varscan2
- DTWD1 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 65/294 reads (22%) | catalogued as COSV99233454; called by muse, mutect2, varscan2
- DUSP1 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99495800; called by muse, mutect2, varscan2
- DVL3 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as rs146812695; called by muse, mutect2, varscan2
- EAF2 | c.334del p.T112Qfs*30 | Frame Shift Del (DEL) | VAF 75/158 reads (47%) | catalogued as rs746509911; called by mutect2, varscan2
- EBLN2 | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 68/151 reads (45%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as rs376896494; called by muse, mutect2, varscan2
- ECT2L | c.2260-2A>G p.X754_splice | Splice Site (SNP) | VAF 36/85 reads (42%) | catalogued as rs747470215, COSV62886645; called by muse, mutect2, varscan2
- EDAR | c.482G>A p.G161D | Missense Mutation (SNP) | VAF 16/25 reads (64%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV99302825; called by muse, mutect2, varscan2
- EDC4 | c.533G>A p.S178N | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.15); catalogued as COSV54646277, COSV99534122; called by muse, mutect2, varscan2
- EFHD1 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 101/242 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.107); catalogued as rs757443440, COSV99081446; called by muse, mutect2, varscan2
- EGR1 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 105/253 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53518033; called by muse, mutect2, varscan2
- EGR2 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 74/170 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746273681, COSV99653873; called by muse, mutect2, varscan2
- EHD3 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 65/139 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59031523; called by muse, mutect2, varscan2
- EHMT2 | c.2218C>T p.R740C | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs144112397; called by muse, mutect2, varscan2
- EIF4G3 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768014443, COSV51691660; called by muse, mutect2, varscan2
- ELL3 | c.237G>T p.E79D | Missense Mutation (SNP) | VAF 70/184 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100082410; called by muse, mutect2, varscan2
- EPB41L1 | c.2587G>A p.V863I | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371978327; called by muse, mutect2, varscan2
- EPHA1 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs770072024, COSV51970809, COSV51975526; called by muse, mutect2, varscan2
- EPHB4 | c.2215C>T p.R739* | Nonsense Mutation (SNP) | VAF 63/171 reads (37%) | catalogued as rs773967187, COSV100639365; called by muse, mutect2, varscan2
- EPN2 | c.1186C>T p.P396S | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as COSV100127250; called by muse, mutect2, varscan2
- EPX | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0.083); catalogued as rs369339605; called by muse, mutect2, varscan2
- ERBB4 | c.167G>A p.C56Y | Missense Mutation (SNP) | VAF 90/199 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99613896; called by muse, mutect2, varscan2
- ERICH3 | c.2515del p.A839Qfs*21 | Frame Shift Del (DEL) | VAF 73/218 reads (33%) | catalogued as COSV58604339; called by mutect2, pindel, varscan2
- ESF1 | c.512del p.N171Tfs*18 | Frame Shift Del (DEL) | VAF 72/180 reads (40%) | catalogued as rs745713173; called by mutect2, varscan2
- ESRP2 | c.1285C>T p.R429* (on ENST00000565858 / NM_001365264.1; = p.R419* on NM_024939.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 73/192 reads (38%) | catalogued as COSV99250976; called by muse, mutect2, varscan2
- EXTL3 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 70/171 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.765); catalogued as rs374083446; called by muse, mutect2, varscan2
- F3 | c.326_328del p.S109del | In Frame Del (DEL) | VAF 15/58 reads (26%) | catalogued as rs1171177725; called by mutect2, pindel, varscan2
- FADS3 | c.1099G>A p.V367M | Missense Mutation (SNP) | VAF 122/307 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1035734117, COSV99605010; called by muse, mutect2, varscan2
- FAH | c.1084A>G p.M362V | Missense Mutation (SNP) | VAF 99/221 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs371659518; called by muse, mutect2, varscan2
- FAM120B | c.2231C>T p.A744V | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750073931, COSV53004837; called by muse, varscan2
- FAM155A | c.1019G>T p.R340M | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV101026085; called by muse, mutect2, varscan2
- FAM189A2 | c.1114G>A p.E372K | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.494); catalogued as COSV99974597; called by muse, mutect2, varscan2
- FAM50B | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs369953711; called by muse, mutect2, varscan2
- FAM71B | c.1453T>C p.Y485H | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100261626; called by muse, mutect2, varscan2
- FAM89B | c.443C>T p.A148V (on ENST00000530349 / NM_001098785.2; = p.A135V on NM_152832.3) | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs774914057, COSV100326035; called by muse, mutect2, varscan2
- FAM98C | c.633G>T p.W211C | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99384742; called by muse, mutect2, varscan2
- FANCB | c.883G>T p.G295* | Nonsense Mutation (SNP) | VAF 50/60 reads (83%) | catalogued as COSV100146268; called by muse, mutect2, varscan2
- FAR1 | c.768+2T>C p.X256_splice | Splice Site (SNP) | VAF 36/147 reads (24%) | catalogued as COSV100701477; called by muse, mutect2, varscan2
- FBLN7 | c.1163G>A p.R388H | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778318785, COSV55616759; called by mutect2, varscan2
- FBN3 | c.3616G>A p.V1206I | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747241812, COSV99559163; called by muse, mutect2, varscan2
- FBXO10 | c.695A>G p.H232R | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs375383268; called by muse, mutect2, varscan2
- FBXO15 | c.1282G>A p.V428I | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1363832799, COSV54043164; called by muse, mutect2, varscan2
- FBXO43 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 47/227 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as rs751533209, COSV71055270; called by muse, mutect2, varscan2
- FBXO47 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 96/263 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as COSV100960492; called by muse, mutect2, varscan2
- FCGBP | c.8420G>A p.R2807Q | Missense Mutation (SNP) | VAF 351/1247 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0.019); catalogued as rs778200930; called by muse, mutect2, varscan2
- FGF12 | c.113G>T p.R38L | Missense Mutation (SNP) | VAF 103/202 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as COSV53162857; called by muse, mutect2, varscan2
- FGF5 | c.265G>A p.G89S | Missense Mutation (SNP) | VAF 79/176 reads (45%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.773); catalogued as rs778270075, COSV100427736; called by muse, mutect2, varscan2
- FGFR2 | c.549del p.N184Tfs*9 | Frame Shift Del (DEL) | VAF 34/81 reads (42%) | catalogued as rs1164513666; called by mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 55/126 reads (44%) | catalogued as rs777980924; called by mutect2, varscan2
- FILIP1 | c.3230G>A p.R1077Q | Missense Mutation (SNP) | VAF 151/324 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs1268558002, COSV99383490; called by muse, mutect2, varscan2
- FILIP1L | c.1072dup p.I358Nfs*3 (on ENST00000354552 / NM_182909.3; = p.I118Nfs*3 on NM_014890.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 60/176 reads (34%) | catalogued as rs1311581659; called by mutect2, pindel, varscan2
- FIS1 | c.349G>T p.A117S | Missense Mutation (SNP) | VAF 78/190 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.429); catalogued as COSV99778855; called by muse, mutect2, varscan2
- FKBP11 | c.515T>A p.I172N | Missense Mutation (SNP) | VAF 78/238 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99872628; called by muse, mutect2, varscan2
- FKBP14 | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 111/289 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99321186; called by muse, mutect2, varscan2
- FLNC | c.4541C>T p.T1514M | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.103); catalogued as rs1159701068, COSV100367410; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMNL3 | c.1885G>A p.A629T | Missense Mutation (SNP) | VAF 74/280 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.059); catalogued as COSV99525394; called by muse, varscan2
- FMO5 | c.263T>G p.V88G | Missense Mutation (SNP) | VAF 65/173 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV99566429; called by muse, mutect2, varscan2
- FOXJ2 | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 168/305 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.124); catalogued as rs757750422, COSV99367950; called by muse, mutect2, varscan2
- FOXN4 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 100/182 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs759819045, COSV100141966; called by muse, varscan2
- FOXO3 | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 162/398 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749629630, COSV100669429; called by muse, mutect2, varscan2
- FOXO3 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 154/368 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs1322957199, COSV100669434; called by muse, mutect2, varscan2
- FRMD1 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs372041975; called by muse, mutect2, varscan2
- FRMPD4 | c.1857G>T p.E619D | Missense Mutation (SNP) | VAF 36/41 reads (88%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.047); catalogued as COSV101041737; called by muse, mutect2, varscan2
- FRZB | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 65/183 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs924566733, COSV99717197; called by muse, mutect2, varscan2
- FUT9 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.945); catalogued as rs1339153685, COSV56146372; called by muse, mutect2, varscan2
- FUZ | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 54/100 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs773367242, COSV100570933, COSV58240836; called by muse, mutect2, varscan2
- FZD1 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV55312774, COSV99842299; called by muse, mutect2, varscan2
- GABBR2 | c.1235C>T p.T412M | Missense Mutation (SNP) | VAF 104/227 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755692994, COSV52292416; called by muse, varscan2
- GABBR2 | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as rs778365249, COSV52296116; called by muse, mutect2, varscan2
- GABRB3 | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100161964, COSV54652552, COSV54658230; called by muse, mutect2, varscan2
- GABRP | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 43/85 reads (51%) | catalogued as rs773277344, COSV54662976; called by muse, mutect2, varscan2
- GABRQ | c.1222del p.L408Wfs*10 | Frame Shift Del (DEL) | VAF 128/201 reads (64%) | catalogued as rs1569454161; called by mutect2, pindel, varscan2
- GALNTL6 | c.841G>T p.G281* | Nonsense Mutation (SNP) | VAF 47/126 reads (37%) | catalogued as COSV101559969; called by muse, mutect2, varscan2
- GCNT3 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 36/100 reads (36%) | catalogued as COSV101251698; called by muse, mutect2, varscan2
- GCOM1 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.095); catalogued as rs770449271, COSV51088477; called by muse, mutect2, varscan2
- GEMIN2 | c.137del p.P46Rfs*8 | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | catalogued as rs1566527852; called by mutect2, pindel, varscan2
- GGCX | c.1076G>A p.R359H | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.86); catalogued as rs200774203, COSV52089587; called by muse, mutect2, varscan2
- GJA8 | c.157G>A p.V53M | Missense Mutation (SNP) | VAF 75/164 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs782396294, COSV53788023, COSV99568939; called by muse, mutect2, varscan2
- GK2 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 192/488 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.275); catalogued as rs752639242, COSV100725869, COSV62626389; called by muse, mutect2, varscan2
- GLCCI1 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs777220141, COSV99779982; called by muse, mutect2, varscan2
- GLDC | c.2353G>A p.V785I | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs372101832; called by muse, mutect2, varscan2
- GLIS3 | c.2044C>T p.H682Y | Missense Mutation (SNP) | VAF 75/201 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs751461025, COSV100172813; called by muse, mutect2, varscan2
- GLMN | c.924C>T p.S308= | Splice Region (SNP) | VAF 29/130 reads (22%) | catalogued as rs1371030400, COSV100949902; called by muse, mutect2, varscan2
- GLP2R | c.1576C>T p.R526W | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs1445249178, COSV99301360; called by muse, mutect2, varscan2
- GLRA2 | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 88/104 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54336582; called by muse, varscan2
- GLRX3 | c.475T>C p.C159R | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100487822; called by muse, mutect2, varscan2
- GLYCTK | c.1265G>A p.R422Q | Missense Mutation (SNP) | VAF 80/183 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769693391, COSV59793374; called by muse, mutect2, varscan2
- GMPR | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 66/155 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs768978971, COSV52472577, COSV99439585; called by muse, mutect2, varscan2
- GOLGA2 | c.2932C>T p.R978W | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as rs1338016366, COSV57855430; called by mutect2, varscan2
- GPBAR1 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV99946083; called by muse, mutect2, varscan2
- GPR39 | c.685G>A p.V229M | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as rs1461565867, COSV61422278; called by muse, mutect2, varscan2
- GPRC5B | c.1055A>G p.N352S | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated (0.77); PolyPhen benign (0.138); catalogued as rs1442105793, COSV100244345; called by muse, varscan2
- GPX3 | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100161006; called by muse, mutect2, varscan2
- GRIA1 | c.2498G>A p.R833H | Missense Mutation (SNP) | VAF 75/203 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.117); catalogued as rs758170711, COSV53620238, COSV99597328; called by muse, mutect2, varscan2
- GRIN3A | c.2653G>A p.A885T | Missense Mutation (SNP) | VAF 84/219 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs372945887, COSV100701297; called by muse, mutect2, varscan2
- GRIP2 | c.3140G>A p.R1047Q (on ENST00000619221; = p.R950Q on NM_001080423.4) | Missense Mutation (SNP) | VAF 85/206 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.072); catalogued as rs751884082, COSV99816799; called by muse, mutect2, varscan2
- GTF2F1 | c.1474G>A p.V492M | Missense Mutation (SNP) | VAF 103/340 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.971); catalogued as rs199893553, COSV55532869, COSV99831652; called by muse, mutect2, varscan2
- GTF2IRD1 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs1480640371, COSV56084939; called by muse, mutect2, varscan2
- GUCA1B | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs755162612, COSV99273727; called by muse, mutect2, varscan2
- GUCY2D | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.022); catalogued as rs567708710, COSV99643599; called by muse, mutect2, varscan2
- GUCY2D | c.2281C>T p.R761W | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs200637525; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GXYLT2 | c.1005G>A p.W335* | Nonsense Mutation (SNP) | VAF 28/116 reads (24%) | catalogued as COSV101274595, COSV101274596; called by muse, mutect2, varscan2
- GZMM | c.43del p.A15Pfs*4 | Frame Shift Del (DEL) | VAF 48/114 reads (42%) | catalogued as rs1260022730; called by mutect2, varscan2
- HCN1 | c.2228C>T p.P743L | Missense Mutation (SNP) | VAF 77/183 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV57491706, COSV57502530; called by muse, mutect2, varscan2
- HCN3 | c.2192G>A p.R731H | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.288); catalogued as rs767894046, COSV61361937; called by muse, mutect2, varscan2
- HCN4 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 37/103 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs998387579, COSV56086816; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HCRTR2 | c.32del p.P11Lfs*11 | Frame Shift Del (DEL) | VAF 64/186 reads (34%) | catalogued as rs755844571, COSV63794110; called by mutect2, pindel
- HDAC9 | c.2065G>T p.E689* | Nonsense Mutation (SNP) | VAF 9/134 reads (7%) | catalogued as COSV67781348, COSV67783378; called by muse, mutect2
- HDC | c.1245T>C p.G415= | Splice Region (SNP) | VAF 38/101 reads (38%) | catalogued as COSV99983707; called by muse, mutect2, varscan2
- HDLBP | c.1818+2T>C p.X606_splice | Splice Site (SNP) | VAF 49/246 reads (20%) | catalogued as COSV60500063; called by muse, mutect2, varscan2
- HEXIM2 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs760708659, COSV56235817; called by muse, mutect2, varscan2
- HEY2 | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.806); catalogued as rs769963246, COSV64239865; called by muse, mutect2, varscan2
- HEY2 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs1280261143, COSV100856247; called by muse, varscan2
- HIVEP2 | c.515A>G p.Q172R | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as COSV99171389; called by muse, mutect2, varscan2
- HLA-DQB1 | c.535del p.I180Lfs*12 | Frame Shift Del (DEL) | VAF 46/112 reads (41%) | catalogued as rs751976368; called by mutect2, varscan2
- HNF4A | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs1223493898, COSV100290893; called by muse, mutect2
- HNF4A | c.1315G>T p.G439C | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.156); catalogued as COSV100290895; called by muse, varscan2
- HOXA6 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 96/222 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs753984515, COSV99762032; called by muse, mutect2, varscan2
- HOXB6 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99494296; called by muse, mutect2, varscan2
- HOXB9 | c.413T>C p.L138S | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.26); catalogued as rs200221711, COSV100239410; called by muse, mutect2, varscan2
- HPR | c.332C>T p.A111V | Missense Mutation (SNP) | VAF 114/195 reads (58%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); catalogued as COSV99930653; called by muse, mutect2, varscan2
- HS2ST1 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 66/194 reads (34%) | catalogued as rs865888400, COSV63352001; called by muse, mutect2, varscan2
- HTR3E | c.919del p.L307Sfs*12 (on ENST00000415389 / NM_001256613.1; = p.L322Sfs*12 on NM_182589.2) | Frame Shift Del (DEL) | VAF 65/150 reads (43%) | catalogued as rs754509192; called by mutect2, pindel, varscan2
- HVCN1 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 72/264 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.311); catalogued as COSV99656942; called by muse, mutect2, varscan2
- ICAM5 | c.1760T>C p.V587A | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.112); catalogued as COSV99702999; called by muse, mutect2, varscan2
- IFT140 | c.3251C>T p.A1084V | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757199524, COSV54152205, COSV54153732; called by muse, mutect2, varscan2
- IFT81 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as rs765241061, COSV54365872; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGF1R | c.2066C>T p.T689I | Missense Mutation (SNP) | VAF 72/161 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV99147900; called by muse, mutect2, varscan2
- IGF2R | c.4751T>C p.V1584A | Missense Mutation (SNP) | VAF 122/262 reads (47%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV100806609; called by muse, varscan2
- IGHG4 | c.350del p.G117Dfs*16 | Frame Shift Del (DEL) | VAF 48/283 reads (17%) | catalogued as rs1475796782; called by mutect2, varscan2
- IGHV3-72 | c.191T>C p.L64P | Missense Mutation (SNP) | VAF 119/210 reads (57%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.618); catalogued as COSV101455355; called by muse, mutect2, varscan2
- IGHV5-51 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs782566695; called by muse, mutect2
- IGSF8 | c.1282C>T p.R428W | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs777061327, COSV58757947; called by muse, mutect2, varscan2
- IKBKB | c.634G>A p.A212T | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV100645534; called by muse, mutect2, varscan2
- IL18BP | c.275T>C p.F92S | Missense Mutation (SNP) | VAF 61/143 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV99474382; called by muse, mutect2, varscan2
- IL21R | c.1078G>A p.G360S | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.019); catalogued as COSV61972222; called by muse, mutect2, varscan2
- IL27RA | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); catalogued as rs370071884; called by muse, mutect2, varscan2
- INHBE | c.1010C>T p.T337M | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs760258476, COSV99875144; called by muse, mutect2, varscan2
- INPP5D | c.1301C>T p.T434M (on ENST00000445964 / NM_001017915.3; = p.T433M on NM_005541.5) | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1455642398, COSV64039767; called by muse, mutect2, varscan2
- INPPL1 | c.2927dup p.P977Tfs*7 | Frame Shift Ins (INS) | VAF 12/30 reads (40%) | catalogued as rs749079348; called by mutect2, varscan2
- INTS5 | c.2678G>A p.R893H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs778371875, COSV57952124; called by muse, mutect2, varscan2
- IQSEC2 | c.1208C>A p.P403H (on ENST00000642864 / NM_001111125.3; = p.P198H on NM_015075.2) | Missense Mutation (SNP) | VAF 99/120 reads (83%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV100944657; called by muse, mutect2, varscan2
- IRF3 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as rs1456700189, COSV55863507; called by muse, mutect2, varscan2
- IRS1 | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs942813013, COSV59335233; called by muse, mutect2, varscan2
- ISG15 | c.178del p.A61Pfs*22 | Frame Shift Del (DEL) | VAF 52/158 reads (33%) | catalogued as rs1170724503, COSV101046047; called by mutect2, varscan2
- ISLR2 | c.2041G>A p.A681T | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.018); catalogued as rs777224671, COSV62303447; called by muse, mutect2, varscan2
- ITFG1 | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs758393141, COSV57748092; called by mutect2, varscan2
- ITGA2B | c.1496C>A p.P499H | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99288392; called by muse, mutect2, varscan2
- ITGBL1 | c.1325A>T p.Y442F | Missense Mutation (SNP) | VAF 162/433 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.265); catalogued as COSV66004898; called by muse, varscan2
- ITIH1 | c.1790C>T p.S597L | Missense Mutation (SNP) | VAF 72/154 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs775722288, COSV99834792; called by muse, mutect2, varscan2
- ITIH3 | c.1343G>T p.R448L | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs199816198, COSV101406879; called by muse, mutect2, varscan2
- ITPR3 | c.6784C>T p.R2262C | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1438477715, COSV100966725; called by muse, mutect2, varscan2
- IZUMO1 | c.344T>C p.L115S | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99710375; called by muse, mutect2
- JAK1 | c.1016del p.N339Ifs*3 | Frame Shift Del (DEL) | VAF 150/434 reads (35%) | catalogued as rs1181132297; called by mutect2, pindel, varscan2
- JAKMIP3 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs754433822, COSV100058422; called by muse, mutect2, varscan2
- JAKMIP3 | c.765G>T p.E255D | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.065); catalogued as COSV100058423; called by muse, mutect2, varscan2
- JHY | c.935T>A p.I312N | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV57080252; called by muse, mutect2
- KAT6A | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 84/189 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs372273756; called by muse, mutect2, varscan2
- KCND1 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 81/98 reads (83%) | SIFT deleterious (0.05); PolyPhen benign (0.109); catalogued as rs782488264, COSV99501586; called by muse, mutect2, varscan2
- KCNV2 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 98/246 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1449828854, COSV101172437; called by muse, mutect2, varscan2
- KCTD19 | c.943C>T p.R315* | Nonsense Mutation (SNP) | VAF 102/222 reads (46%) | catalogued as rs776633709, COSV100430571; called by muse, mutect2, varscan2
- KDM3B | c.331C>T p.R111* | Nonsense Mutation (SNP) | VAF 8/228 reads (4%) | catalogued as COSV100070223; called by muse, mutect2
- KDR | c.2315C>T p.A772V | Missense Mutation (SNP) | VAF 73/175 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.068); catalogued as rs199982402, COSV55771246; called by muse, mutect2, varscan2
- KIAA0753 | c.1552C>T p.R518C | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.319); catalogued as rs370311617; called by muse, mutect2, varscan2
- KIF16B | c.3569G>A p.R1190H | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1345910626, COSV61704500; called by muse, mutect2, varscan2
- KIF23 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 117/245 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as rs756964640, COSV52980273; called by muse, mutect2, varscan2
- KIF26B | c.2272G>A p.A758T | Missense Mutation (SNP) | VAF 63/118 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs769468332, COSV100833514, COSV63636821; called by muse, mutect2, varscan2
- KLF15 | c.1142A>G p.Y381C | Missense Mutation (SNP) | VAF 105/255 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99955007; called by muse, mutect2, varscan2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 50/119 reads (42%) | catalogued as rs749194179; called by mutect2, pindel
- KLHL5 | c.1433C>T p.T478I | Missense Mutation (SNP) | VAF 93/193 reads (48%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.516); catalogued as COSV54679536, COSV99784591; called by muse, mutect2, varscan2
- KLRB1 | c.58A>T p.S20C | Missense Mutation (SNP) | VAF 28/396 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV99987129; called by muse, mutect2
- KMT2B | c.3509G>A p.R1170H | Missense Mutation (SNP) | VAF 156/393 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1313553140, COSV99718516; called by muse, mutect2, varscan2
- KRT38 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 78/195 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs767626446, COSV55846793; called by muse, mutect2, varscan2
- KRT74 | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 102/168 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs775208348, COSV99977331; called by muse, mutect2, varscan2
- LAMB4 | c.673A>G p.N225D | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99222155; called by muse, mutect2, varscan2
- LAT | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs756908098, COSV100208756; called by muse, mutect2, varscan2
- LAYN | c.700G>A p.A234T (on ENST00000375615 / NM_001258390.1; = p.A226T on NM_178834.5) | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.154); catalogued as COSV100986122; called by muse, varscan2
- LCT | c.1333G>A p.G445S | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs1340454714, COSV51543851; called by muse, mutect2, varscan2
- LDB1 | c.756G>A p.M252I (on ENST00000425280 / NM_001321612.2; = p.M216I on NM_003893.5) | Missense Mutation (SNP) | VAF 57/138 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100756287; called by muse, mutect2, varscan2
- LDLRAD3 | c.103T>C p.F35L | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100214117; called by muse, mutect2, varscan2
- LHX8 | c.1051C>A p.L351M | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99632703; called by muse, mutect2, varscan2
- LIAS | c.107del p.K36Rfs*31 | Frame Shift Del (DEL) | VAF 112/264 reads (42%) | catalogued as rs748571616; called by mutect2, varscan2
- LOXL2 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs772042943, COSV66690339; called by muse, mutect2, varscan2
- LPAR3 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 123/306 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.306); catalogued as rs751975084, COSV65454820; called by muse, mutect2, varscan2
- LPIN3 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs765565818, COSV100952809; called by muse, mutect2, varscan2
- LRIT1 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 52/121 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as rs1330461774, COSV100927963; called by muse, mutect2, varscan2
- LRRC28 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 71/175 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs761561702, COSV100113183; called by muse, mutect2, varscan2
- LRRC37B | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.199); catalogued as rs754480928, COSV100495890; called by muse, mutect2, varscan2
- LRRC41 | c.2137C>T p.R713C | Missense Mutation (SNP) | VAF 73/171 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1438184499, COSV58441819; called by muse, mutect2, varscan2
- LRRC4C | c.1753C>A p.L585M | Missense Mutation (SNP) | VAF 146/366 reads (40%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.104); catalogued as rs1268402542, COSV99536378; called by muse, mutect2, varscan2
- LRRC59 | c.803T>A p.V268E | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as COSV99869263; called by muse, mutect2, varscan2
- LRRC8A | c.2270C>T p.T757M | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.577); catalogued as rs557710052, COSV99396123; called by muse, mutect2, varscan2
- LRRIQ1 | c.4624dup p.I1542Nfs*8 | Frame Shift Ins (INS) | VAF 36/80 reads (45%) | catalogued as rs745692987; called by mutect2, varscan2
- LRRK1 | c.4490C>T p.A1497V | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs767617347, COSV99436759; called by muse, mutect2, varscan2
- LRRK2 | c.4648C>T p.R1550W | Missense Mutation (SNP) | VAF 55/198 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as rs1555188401, COSV100108498; called by muse, mutect2, varscan2
- LTBP4 | c.4706G>A p.R1569H (on ENST00000308370 / NM_001042544.1; = p.R1532H on NM_003573.2) | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.354); catalogued as rs897376392; called by muse, varscan2
- MAGI1 | c.3857C>T p.S1286L | Missense Mutation (SNP) | VAF 197/497 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV58312409; called by muse, mutect2, varscan2
- MAGI2 | c.3424-2A>G p.X1142_splice | Splice Site (SNP) | VAF 41/114 reads (36%) | catalogued as COSV100831576; called by muse, mutect2, varscan2
- MAN2B2 | c.1404C>T p.S468= | Splice Region (SNP) | VAF 40/101 reads (40%) | catalogued as rs1159779598; called by muse, varscan2
- MAP2K2 | c.311A>G p.H104R | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.029); catalogued as COSV53569164; called by muse, mutect2, varscan2
- MAP2K7 | c.858C>T p.P286= | Splice Region (SNP) | VAF 48/126 reads (38%) | catalogued as rs757758116; called by muse, varscan2
- MAP3K21 | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 95/212 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759521299, COSV100786190; called by muse, varscan2
- MAP3K21 | c.1420G>A p.V474M | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV100786191; called by muse, mutect2, varscan2
- MAP3K4 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62334571; called by muse, mutect2, varscan2
- MAP7D3 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 64/78 reads (82%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs749992584, COSV60172939; called by muse, mutect2, varscan2
- MAPK8 | c.16C>T p.R6C | Missense Mutation (SNP) | VAF 65/172 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs773780784, COSV64410081; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1648C>T p.R550W | Missense Mutation (SNP) | VAF 72/159 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99167578; called by muse, mutect2, varscan2
- MARK1 | c.1642C>T p.R548* | Nonsense Mutation (SNP) | VAF 72/179 reads (40%) | catalogued as rs1346347772, COSV65068250; called by muse, mutect2, varscan2
- MAST1 | c.2459G>A p.R820H | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.732); catalogued as rs1346281765; called by muse, mutect2, varscan2
- MAST1 | c.2948C>T p.A983V | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52249519, COSV99261970; called by muse, mutect2, varscan2
- MATN2 | c.382C>T p.R128W | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs377009254; called by muse, mutect2, varscan2
- MB21D2 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.117); catalogued as COSV101164866; called by muse, mutect2, varscan2
- MBD6 | c.2200del p.Q734Nfs*18 | Frame Shift Del (DEL) | VAF 32/91 reads (35%) | catalogued as rs749738168; called by mutect2, varscan2
- MCF2L2 | c.1858del p.R620Afs*16 | Frame Shift Del (DEL) | VAF 36/115 reads (31%) | catalogued as COSV100193332; called by mutect2, pindel, varscan2
- MCF2L2 | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 41/95 reads (43%) | catalogued as rs1450813503, COSV61053896; called by muse, mutect2, varscan2
- MED13 | c.4844G>T p.S1615I | Missense Mutation (SNP) | VAF 69/149 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV101180675; called by muse, mutect2, varscan2
- MED13 | c.2531T>C p.I844T | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.419); catalogued as COSV101180676; called by muse, mutect2, varscan2
- MED24 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV100672738; called by muse, mutect2
- MEGF6 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 387/831 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs373558942; called by muse, mutect2, varscan2
- MEGF8 | c.1668C>T p.D556= | Splice Region (SNP) | VAF 38/85 reads (45%) | catalogued as rs370015031; called by muse, mutect2, varscan2
- MEPCE | c.1787T>G p.L596R | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52769860; called by muse, mutect2, varscan2
- METTL16 | c.962T>C p.M321T | Missense Mutation (SNP) | VAF 78/193 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV99562918; called by muse, varscan2
- METTL16 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.104); catalogued as rs768657565, COSV99562920; called by muse, mutect2, varscan2
- MFSD8 | c.1484C>T p.T495I | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.107); catalogued as COSV99614044; called by muse, mutect2, varscan2
- MIEF1 | c.955G>A p.G319S | Missense Mutation (SNP) | VAF 53/91 reads (58%) | SIFT tolerated (0.46); PolyPhen benign (0.265); catalogued as rs143931307; called by muse, mutect2, varscan2
- MITF | c.1517G>A p.R506Q (on ENST00000448226 / NM_006722.3; = p.R406Q on NM_000248.4) | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1018390529, COSV58833050; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MKI67 | c.5717C>T p.T1906M | Missense Mutation (SNP) | VAF 279/730 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs776996722, COSV100895967; called by muse, mutect2, varscan2
- MLF2 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as rs773985602, COSV99180046; called by muse, mutect2, varscan2
- MLIP | c.1113+1G>T p.X371_splice | Splice Site (SNP) | VAF 39/101 reads (39%) | catalogued as COSV99228055; called by muse, mutect2, varscan2
- MMP16 | c.132+2T>C p.X44_splice | Splice Site (SNP) | VAF 97/135 reads (72%) | catalogued as COSV99685241; called by muse, mutect2, varscan2
- MMP7 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 134/268 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs145006821; called by muse, mutect2, varscan2
- MMP9 | c.788A>G p.D263G | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100812297; called by muse, mutect2, varscan2
- MMP9 | c.1210G>A p.G404S | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751218589, COSV100812298; called by muse, mutect2, varscan2
- MNDA | c.42T>G p.F14L | Missense Mutation (SNP) | VAF 92/220 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100933214; called by muse, mutect2, varscan2
- MNT | c.1678C>T p.Q560* | Nonsense Mutation (SNP) | VAF 57/142 reads (40%) | catalogued as COSV99437854; called by muse, mutect2, varscan2
- MON2 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 119/209 reads (57%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1180236114, COSV99741210; called by muse, mutect2, varscan2
- MROH1 | c.2401C>T p.R801C | Missense Mutation (SNP) | VAF 62/243 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs1053634097; called by muse, mutect2, varscan2
- MRPL37 | c.1040C>T p.T347M | Missense Mutation (SNP) | VAF 148/345 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.923); catalogued as rs753105572, COSV100288959; called by muse, mutect2, varscan2
- MSN | c.445G>A p.G149R | Missense Mutation (SNP) | VAF 62/71 reads (87%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs757131925, COSV100814024; called by muse, mutect2, varscan2
- MTMR10 | c.2234G>A p.G745E | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100075667; called by muse, mutect2, varscan2
- MTRES1 | c.79C>T p.R27* | Nonsense Mutation (SNP) | VAF 30/65 reads (46%) | catalogued as rs1554227380, COSV100261072; called by muse, mutect2, varscan2
- MTTP | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV99644528; called by muse, mutect2, varscan2
- MUC16 | c.30625del p.T10209Hfs*19 | Frame Shift Del (DEL) | VAF 113/312 reads (36%) | catalogued as COSV67487448; called by mutect2, pindel, varscan2
- MUSK | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.014); catalogued as rs774463260, COSV99503417; called by muse, mutect2, varscan2
- MXRA5 | c.6568G>A p.A2190T | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.558); catalogued as COSV54249775; called by muse, mutect2, varscan2
- MXRA5 | c.6182C>T p.P2061L | Missense Mutation (SNP) | VAF 60/70 reads (86%) | SIFT tolerated (0.98); PolyPhen benign (0.39); catalogued as rs200199741, COSV99475235; called by muse, mutect2, varscan2
- MXRA5 | c.2305C>T p.R769* | Nonsense Mutation (SNP) | VAF 132/160 reads (83%) | catalogued as COSV99475236; called by muse, varscan2
- MXRA7 | c.557C>T p.T186M | Missense Mutation (SNP) | VAF 14/44 reads (32%) | PolyPhen probably damaging (0.999); catalogued as rs1038906917, COSV63321189; called by muse, mutect2, varscan2
- MYBL1 | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 337/508 reads (66%) | catalogued as COSV101576438; called by muse, mutect2, varscan2
- MYBPC3 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 41/94 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.745); catalogued as rs373638535, CM138715, COSV99908560; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYBPH | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 90/256 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146696842; called by muse, mutect2, varscan2
- MYF5 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 58/175 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57356615; called by muse, mutect2, varscan2
- MYH6 | c.5095C>T p.R1699W | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766345714, COSV100676109; called by muse, mutect2, varscan2
- MYH7 | c.4606G>A p.E1536K | Missense Mutation (SNP) | VAF 66/176 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs779315151, CM115873, COSV62516010; called by muse, varscan2
- MYL9 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs775610439, COSV99640899; called by muse, mutect2, varscan2
- MYO10 | c.4306G>A p.A1436T | Missense Mutation (SNP) | VAF 89/215 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.687); catalogued as rs753505470, COSV99944382; called by muse, mutect2, varscan2
- MYO10 | c.1104G>T p.Q368H | Missense Mutation (SNP) | VAF 46/175 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV101569722; called by muse, mutect2, varscan2
- MYO1B | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100268304; called by muse, mutect2, varscan2
- MYO7A | c.4921G>A p.E1641K | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.92); catalogued as rs767975012, CM1310726, COSV101288995; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYOM2 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 259/643 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs375889597; called by muse, mutect2, varscan2
- MYOM3 | c.49del p.Q17Rfs*57 | Frame Shift Del (DEL) | VAF 150/437 reads (34%) | catalogued as rs532144295; called by mutect2, pindel, varscan2
- MYOZ1 | c.572C>A p.A191D | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100831739; called by muse, mutect2, varscan2
- MYOZ3 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99770520; called by muse, mutect2, varscan2
- MYRIP | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 71/156 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs769986510, COSV100218023; called by muse, mutect2, varscan2
- MYT1L | c.1796C>T p.S599L | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as rs1263025144, COSV101217690; called by muse, mutect2, varscan2
- NADK | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 73/142 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs750455546, COSV100410514; called by muse, mutect2, varscan2
- NAIF1 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs1383950060, COSV100895683; called by muse, varscan2
- NARS2 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 80/181 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55252549; called by muse, mutect2, varscan2
- NARS2 | c.737A>T p.N246I | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV55249556, COSV99806816; called by muse, mutect2, varscan2
- NAXD | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs752108793, COSV57288631; called by muse, mutect2, varscan2
- NBEAL2 | c.4582C>T p.R1528C | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV52759404; called by muse, varscan2
- NCBP1 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.371); catalogued as COSV100912501; called by muse, mutect2, varscan2
- NCL | c.1811G>A p.R604Q | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.557); catalogued as COSV100502151; called by muse, mutect2, varscan2
- NCOA2 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.022); catalogued as rs1217727548, COSV71763398; called by muse, mutect2, varscan2
- NCOA5 | c.1010del p.G337Afs*38 | Frame Shift Del (DEL) | VAF 55/150 reads (37%) | catalogued as rs1200193975; called by mutect2, pindel, varscan2
- NCOR2 | c.3904del p.H1302Mfs*12 | Frame Shift Del (DEL) | VAF 31/88 reads (35%) | catalogued as COSV100657106; called by mutect2, varscan2
- NEBL | c.1381G>T p.G461* | Nonsense Mutation (SNP) | VAF 36/84 reads (43%) | catalogued as COSV65801666; called by muse, mutect2, varscan2
- NECTIN1 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.08); PolyPhen benign (0.375); catalogued as rs148045547; called by muse, mutect2, varscan2
- NECTIN2 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 55/189 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as COSV99374698; called by muse, mutect2, varscan2
- NEDD4L | c.2674G>A p.A892T (on ENST00000400345 / NM_001144967.3; = p.A872T on NM_015277.6) | Missense Mutation (SNP) | VAF 114/249 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV99892932; called by muse, mutect2, varscan2
- NEK8 | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.532); catalogued as rs771755365, COSV52047719; called by muse, mutect2, varscan2
- NELFA | c.716C>T p.A239V (on ENST00000542778; = p.A228V on NM_005663.5) | Missense Mutation (SNP) | VAF 102/203 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as rs1237156456, COSV100372678; called by muse, mutect2, varscan2
- NEUROD1 | c.653C>A p.P218H | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV99716725; called by muse, mutect2, varscan2
- NEXMIF | c.4321G>A p.G1441R | Missense Mutation (SNP) | VAF 78/100 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.235); catalogued as rs745720102, COSV50034642; called by muse, mutect2, varscan2
- NFIB | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 84/198 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66620392; called by muse, mutect2, varscan2
- NICN1 | c.181C>A p.R61S | Missense Mutation (SNP) | VAF 89/238 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV56469044, COSV56471088; called by muse, mutect2, varscan2
- NLE1 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs750583113, COSV50101998; called by muse, mutect2, varscan2
- NLGN2 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.323); catalogued as rs924724424, COSV57212435; called by muse, mutect2, varscan2
- NMUR2 | c.502G>A p.G168S | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs1053157647, COSV54917078, COSV54917864; called by muse, varscan2
- NOS1 | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.442); catalogued as rs1219636809, COSV57613651; called by muse, varscan2
- NOS1 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 155/564 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1451276089, COSV57610696; called by muse, mutect2, varscan2
- NOTCH3 | c.5101G>A p.A1701T | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as COSV54633894; called by muse, mutect2, varscan2
- NPAS4 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 92/238 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as COSV100214676; called by muse, mutect2, varscan2
- NQO2 | c.221A>G p.E74G | Missense Mutation (SNP) | VAF 85/207 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.144); catalogued as COSV100583093; called by muse, mutect2, varscan2
- NRXN1 | c.2566C>T p.R856W | Missense Mutation (SNP) | VAF 59/147 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs796052777, COSV58442242; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NTAN1 | c.831del p.K277Nfs*83 | Frame Shift Del (DEL) | VAF 46/138 reads (33%) | catalogued as COSV55073962; called by mutect2, varscan2
- NTN4 | c.1628A>G p.E543G | Missense Mutation (SNP) | VAF 55/199 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100643608; called by muse, mutect2, varscan2
- NUB1 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 67/139 reads (48%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV100879188; called by muse, mutect2, varscan2
- ODC1 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 47/100 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.634); catalogued as COSV52172852; called by muse, mutect2, varscan2
- OMD | c.1142G>T p.R381M | Missense Mutation (SNP) | VAF 184/394 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV100978998; called by muse, mutect2, varscan2
- OMP | c.311C>A p.A104D | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV99581536; called by muse, mutect2, varscan2
- OR10P1 | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs752296913, COSV100548082; called by muse, mutect2, varscan2
- OR2L13 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 114/264 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as COSV63555839; called by muse, mutect2, varscan2
- OR2T27 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as rs543746159, COSV61281246, COSV61283337; called by muse, mutect2, varscan2
- OR51S1 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as rs776320504, COSV100437302; called by muse, varscan2
- OR5M10 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 187/485 reads (39%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.595); catalogued as rs566095437, COSV73242337; called by muse, mutect2, varscan2
- OR6Q1 | c.830T>A p.V277E | Missense Mutation (SNP) | VAF 80/153 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100108974; called by muse, mutect2, varscan2
- OR7A17 | c.368T>C p.F123S | Missense Mutation (SNP) | VAF 99/239 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV100541532; called by muse, mutect2, varscan2
- OTOA | c.1961T>C p.V654A (on ENST00000286149; = p.V640A on NM_144672.4) | Missense Mutation (SNP) | VAF 82/168 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.018); catalogued as COSV99623211; called by muse, mutect2, varscan2
- OTUD4 | c.254G>C p.G85A (on ENST00000447906 / NM_001366057.1; = p.G20A on NM_017493.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 129/304 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56851155, COSV99668975; called by muse, mutect2, varscan2
- P2RY1 | c.878C>A p.P293Q | Missense Mutation (SNP) | VAF 78/184 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0.226); catalogued as COSV100521592; called by muse, mutect2, varscan2
- P2RY12 | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764657007, COSV99850811; called by muse, mutect2, varscan2
- PABPC1L | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 45/122 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs199499305; called by muse, mutect2, varscan2
- PACSIN1 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as COSV99762796; called by muse, mutect2, varscan2
- PADI6 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs529584194, COSV100639873; called by muse, mutect2, varscan2
- PADI6 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 94/225 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as rs754193133, COSV100639874; called by muse, mutect2, varscan2
- PAFAH1B3 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.08); catalogued as rs771659012, COSV50647904; called by muse, mutect2, varscan2
- PAK5 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 310/727 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as rs991533102, COSV62023211; called by muse, varscan2
- PAN3 | c.1043A>G p.K348R | Missense Mutation (SNP) | VAF 54/134 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.73); catalogued as COSV99144478; called by muse, mutect2, varscan2
- PAPOLG | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 104/254 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.044); catalogued as rs749124361, COSV53181497; called by muse, mutect2, varscan2
- PAPPA | c.2221C>T p.R741C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1457198734, COSV100072492; called by muse, mutect2, varscan2
- PARD6A | c.541G>A p.V181M | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); catalogued as COSV99537263; called by muse, mutect2, varscan2
- PAX3 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 105/268 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD920899, CM102004, COSV99286285; called by muse, mutect2, varscan2
- PAX6 | c.357C>T p.S119= | Splice Region (SNP) | VAF 52/127 reads (41%) | catalogued as rs121907928, CD082176, CM013024, CM993965, COSV53794419, COSV99570036; called by muse, mutect2, varscan2
- PC | c.2929C>T p.R977W | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs916937580, COSV100546909; called by muse, mutect2, varscan2
- PC | c.1571C>A p.P524H | Missense Mutation (SNP) | VAF 154/308 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV100540570; called by muse, mutect2, varscan2
- PCDH9 | c.1667C>T p.A556V | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.572); catalogued as rs753210691, COSV60527839, COSV60592737; called by muse, mutect2
- PCDHA2 | c.1930C>T p.R644* | Nonsense Mutation (SNP) | VAF 82/215 reads (38%) | catalogued as rs143944331, COSV65365419; called by muse, mutect2, varscan2
- PCDHA3 | c.1108G>A p.A370T | Missense Mutation (SNP) | VAF 71/188 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.877); catalogued as rs1290587407, COSV100793021; called by muse, mutect2, varscan2
- PCDHA5 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1393571238, COSV65349067; called by muse, mutect2, varscan2
- PCDHGB3 | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 63/117 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53915678; called by muse, mutect2, varscan2
- PCED1B | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 104/362 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.067); catalogued as COSV101423581; called by muse, mutect2, varscan2
- PCNX3 | c.2036T>C p.L679P | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV100855821; called by muse, mutect2, varscan2
- PCSK5 | c.1829C>T p.P610L | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.489); catalogued as rs1277845846, COSV65094016; called by muse, mutect2, varscan2
- PDGFRB | c.113del p.P38Rfs*15 | Frame Shift Del (DEL) | VAF 24/153 reads (16%) | catalogued as COSV55800592; called by mutect2, pindel, varscan2
- PDPR | c.362G>A p.G121D | Missense Mutation (SNP) | VAF 190/935 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753917254, COSV99847536; called by muse, mutect2, varscan2
- PDZD2 | c.2321G>A p.R774H | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs556048029, COSV56853343; called by muse, mutect2, varscan2
- PDZD2 | c.2900C>T p.A967V | Missense Mutation (SNP) | VAF 85/229 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV56870927; called by muse, mutect2, varscan2
- PDZD7 | c.593C>A p.P198H | Missense Mutation (SNP) | VAF 105/261 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV100931525; called by muse, mutect2, varscan2
- PEAR1 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs150236151, COSV52772369; called by muse, mutect2, varscan2
- PGAM5 | c.287C>A p.A96D | Missense Mutation (SNP) | VAF 56/168 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100452882; called by muse, mutect2, varscan2
- PGAP2 | c.220C>T p.R74C (on ENST00000463452 / NM_001346398.2; = p.R135C on NM_014489.4) | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.099); catalogued as COSV53464819; called by muse, mutect2, varscan2
- PGBD1 | c.2005del p.M669* | Frame Shift Del (DEL) | VAF 79/231 reads (34%) | catalogued as rs781166611; called by mutect2, pindel, varscan2
- PGBD4 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.622); catalogued as rs1298038398, COSV99854651; called by muse, mutect2, varscan2
- PGC | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 38/114 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs531970409, COSV100756795; called by muse, varscan2
- PGF | c.158G>A p.R53Q | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.366); catalogued as rs559671641; called by muse, varscan2
- PGM3 | c.347A>G p.N116S | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV99392073; called by mutect2, varscan2
- PHF21A | c.1955del p.P652Lfs*104 (on ENST00000418153 / NM_001101802.3; = p.P606Lfs*104 on NM_016621.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 58/178 reads (33%) | catalogued as rs761575760; called by mutect2, pindel, varscan2
- PHLPP2 | c.1532G>A p.R511Q | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs372879648, COSV62426387, COSV62427462; called by muse, varscan2
- PHOX2B | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.81); catalogued as rs1192207345, COSV56931547; called by muse, mutect2, varscan2
- PHYHIP | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 83/201 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs771602736, COSV58689031; called by muse, mutect2, varscan2
- PIGR | c.1738G>A p.A580T | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as rs529407537, COSV62903193; called by muse, mutect2, varscan2
- PIK3CA | c.2851C>T p.R951C | Missense Mutation (SNP) | VAF 128/366 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55980465; called by muse, mutect2, varscan2
- PIK3CD | c.58G>A p.V20I | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT tolerated (0.88); PolyPhen benign (0.01); catalogued as rs143116020; called by muse, mutect2, varscan2
- PINX1 | c.474C>T p.G158= | Splice Region (SNP) | VAF 31/119 reads (26%) | catalogued as rs762236736, COSV59108431; called by muse, mutect2, varscan2
- PIWIL2 | c.1664G>A p.R555H | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs772112294, COSV100769106; called by muse, mutect2, varscan2
- PKNOX2 | c.144del p.S49Qfs*35 | Frame Shift Del (DEL) | VAF 95/248 reads (38%) | catalogued as rs1565508191; called by mutect2, pindel, varscan2
- PKP2 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 64/208 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as rs753912985, COSV50732952, COSV99296981; called by muse, mutect2, varscan2
- PLAAT1 | c.520C>T p.Q174* (on ENST00000650797; = p.Q69* on NM_020386.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 57/151 reads (38%) | catalogued as COSV99290458; called by muse, mutect2, varscan2
- PLEKHG3 | c.1790G>A p.R597Q (on ENST00000394691; = p.R653Q on NM_001308147.2) | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs377488568; called by muse, mutect2, varscan2
- PLEKHG4B | c.1205T>G p.L402R (on ENST00000283426; = p.L758R on NM_052909.5) | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99359530; called by muse, mutect2
- PLEKHO1 | c.835C>T p.R279W | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.798); catalogued as rs782519422, COSV99215024; called by muse, mutect2, varscan2
- PLK1 | c.1078_1080del p.E360del | In Frame Del (DEL) | VAF 32/194 reads (16%) | catalogued as rs1230691153; called by pindel, varscan2
- PLXNA1 | c.886G>A p.V296I | Missense Mutation (SNP) | VAF 79/186 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs202007314, COSV52524105, COSV52526230; called by muse, varscan2
- PLXNB1 | c.1468T>C p.S490P | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99601953; called by muse, mutect2, varscan2
- PLXND1 | c.4678G>A p.V1560M | Missense Mutation (SNP) | VAF 60/134 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs762249042, COSV100138794; called by muse, mutect2, varscan2
- PMM1 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs190292776, COSV99347973; called by muse, mutect2, varscan2
- PNKP | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99681482; called by muse, mutect2, varscan2
- POGLUT3 | c.257G>A p.R86Q | Missense Mutation (SNP) | VAF 73/194 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.281); catalogued as rs750568803, COSV100052429; called by muse, mutect2, varscan2
- POLB | c.54G>A p.M18I | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV55346826; called by muse, mutect2, varscan2
- POLM | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1396168979, COSV54242546; called by muse, mutect2, varscan2
- POLR1A | c.1552G>A p.V518M | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs780248678, COSV55691549, COSV55694876; called by muse, mutect2, varscan2
- POLR3C | c.202C>T p.H68Y | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as COSV61937118; called by muse, mutect2, varscan2
- POLR3E | c.1417G>A p.A473T | Missense Mutation (SNP) | VAF 113/215 reads (53%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as rs749348251, COSV100241782; called by muse, mutect2, varscan2
- POM121C | c.2707G>A p.A903T (on ENST00000607367; = p.A661T on NM_001099415.3) | Missense Mutation (SNP) | VAF 134/431 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782333810; called by muse, mutect2, varscan2
- POU5F2 | c.685T>C p.F229L | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); catalogued as COSV101232626; called by muse, varscan2
- PPP1R16B | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55375541; called by muse, varscan2
- PPP2R2D | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 109/262 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV70778911; called by muse, mutect2, varscan2
- PPP4R3B | c.787del p.I263Yfs*40 | Frame Shift Del (DEL) | VAF 96/292 reads (33%) | catalogued as rs1198364136; called by mutect2, pindel, varscan2
- PREX1 | c.4961C>T p.P1654L | Missense Mutation (SNP) | VAF 277/672 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1000110812, COSV100905970, COSV99057784; called by muse, mutect2, varscan2
- PRICKLE3 | c.1534C>T p.R512C | Missense Mutation (SNP) | VAF 120/134 reads (90%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs781985242, COSV66235061; called by muse, varscan2
- PRKACG | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs138280963; called by muse, mutect2, varscan2
- PRKDC | c.9934G>A p.V3312M | Missense Mutation (SNP) | VAF 114/155 reads (74%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs746336789, COSV58061346; called by muse, mutect2, varscan2
- PRMT8 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 55/98 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as rs766069538, COSV54212649; called by muse, varscan2
- PROCA1 | c.824C>A p.P275H (on ENST00000439862 / NM_001366301.1; = p.P247H on NM_152465.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 159/356 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV99972429; called by muse, mutect2, varscan2
- PRPF38A | c.605A>G p.E202G | Missense Mutation (SNP) | VAF 81/191 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.753); catalogued as COSV99933084; called by muse, mutect2, varscan2
- PRPF38B | c.1461dup p.R488Tfs*4 | Frame Shift Ins (INS) | VAF 144/373 reads (39%) | catalogued as rs773200657; called by mutect2, varscan2
- PRPF40B | c.1018C>T p.R340W (on ENST00000380281; = p.R334W on NM_012272.3) | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746174120, COSV56061125, COSV99979152; called by muse, mutect2, varscan2
- PRPH | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV57679187; called by muse, mutect2
- PRR5-ARHGAP8 | c.1262del p.P421Lfs*3 (on ENST00000352766; = p.P342Lfs*3 on NM_181334.5) | Frame Shift Del (DEL) | VAF 41/129 reads (32%) | catalogued as COSV100424356; called by mutect2, pindel, varscan2
- PRR5L | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1237970347, COSV100286809; called by muse, mutect2, varscan2
- PRRC2B | c.5270C>T p.A1757V | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as COSV57646248; called by muse, mutect2, varscan2
- PRRC2C | c.1394G>A p.R465H (on ENST00000367742; = p.R463H on NM_015172.4) | Missense Mutation (SNP) | VAF 191/447 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58913237; called by muse, mutect2, varscan2
- PRSS53 | c.108dup p.K37Qfs*44 | Frame Shift Ins (INS) | VAF 44/127 reads (35%) | catalogued as rs759089621; called by mutect2, varscan2
- PTCH2 | c.1555G>A p.V519I | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs113543298, COSV100941834; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPN23 | c.3040dup p.L1014Pfs*68 | Frame Shift Ins (INS) | VAF 99/262 reads (38%) | catalogued as rs770411657; called by mutect2, varscan2
- PTPN5 | c.149A>G p.Q50R | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV62125760; called by muse, varscan2
- PTPRC | c.124A>G p.S42G | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.721); catalogued as COSV100721928, COSV61406967; called by muse, mutect2, varscan2
- PTPRC | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 114/308 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs1417710516, COSV100721929, COSV61411009; called by muse, mutect2, varscan2
- PTPRK | c.2066A>T p.D689V | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100950053; called by muse, mutect2, varscan2
- PTPRM | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100153784; called by muse, mutect2, varscan2
- PTPRM | c.2018C>T p.A673V | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.088); catalogued as rs770279168, COSV59848745; called by muse, mutect2, varscan2
- PTPRU | c.1897C>T p.R633W | Missense Mutation (SNP) | VAF 53/120 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs757579431, COSV60530658; called by muse, mutect2, varscan2
- PUM1 | c.2539C>T p.R847W | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs775876971, COSV57082236; called by muse, mutect2, varscan2
- PXDN | c.1451C>T p.S484L | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV53226833; called by muse, mutect2, varscan2
- RAB37 | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 104/229 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs773776531, COSV100462394; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs770859492, COSV99424266; called by muse, mutect2, varscan2
- RABGAP1L | c.1514G>A p.C505Y | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99266354; called by muse, mutect2, varscan2
- RAD51AP2 | c.1276dup p.T426Nfs*2 | Frame Shift Ins (INS) | VAF 66/169 reads (39%) | catalogued as rs759722299; called by mutect2, varscan2
- RALBP1 | c.124T>C p.Y42H | Missense Mutation (SNP) | VAF 86/202 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99191857; called by muse, varscan2
- RASGEF1A | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.21); PolyPhen benign (0.117); catalogued as rs764016510, COSV100988613; called by muse, mutect2, varscan2
- RBM15B | c.1621C>T p.R541* | Nonsense Mutation (SNP) | VAF 22/48 reads (46%) | catalogued as COSV100081834, COSV60040760; called by muse, mutect2, varscan2
- RBM27 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 52/149 reads (35%) | catalogued as COSV54587672; called by muse, mutect2, varscan2
- RBM34 | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 106/278 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs909374532, COSV64012778; called by muse, mutect2, varscan2
- RBM45 | c.122T>G p.L41R | Missense Mutation (SNP) | VAF 94/259 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99617382; called by muse, mutect2, varscan2
- RCC2 | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 75/180 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100965093; called by muse, mutect2, varscan2
- RCSD1 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV100827497; called by muse, mutect2, varscan2
- RFFL | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1444080156, COSV99265094; called by muse, mutect2, varscan2
- RIMS1 | c.3596del p.P1199Qfs*46 | Frame Shift Del (DEL) | VAF 37/115 reads (32%) | catalogued as COSV53438532; called by mutect2, pindel, varscan2
- RNASEH2A | c.397G>A p.V133M | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV55551149; called by muse, mutect2, varscan2
- RNF113B | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1287434043, COSV99940240; called by muse, mutect2, varscan2
- RNF123 | c.1629+1del | Frame Shift Del (DEL) | VAF 32/105 reads (30%) | catalogued as COSV59688684; called by mutect2, pindel, varscan2
- ROBO2 | c.332T>A p.V111D | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59933835; called by muse, mutect2, varscan2
- RPAP2 | c.1607T>A p.V536D | Missense Mutation (SNP) | VAF 134/331 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV101528644; called by muse, mutect2, varscan2
- RPTOR | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.867); catalogued as rs768126116, COSV60815685; called by muse, mutect2, varscan2
- RPTOR | c.3622C>T p.R1208W | Missense Mutation (SNP) | VAF 26/57 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as rs1034257924, COSV100154544; called by muse, varscan2
- RSPO3 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 40/99 reads (40%) | catalogued as rs200509277, COSV100759428; called by muse, mutect2, varscan2
- RTN2 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1271589894, COSV55595576; called by muse, mutect2, varscan2
- RYR1 | c.9905del p.P3302Hfs*19 | Frame Shift Del (DEL) | VAF 70/185 reads (38%) | catalogued as rs749656679; called by mutect2, pindel
- SAGE1 | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 184/220 reads (84%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61013035, COSV61018450; called by muse, mutect2, varscan2
- SCN2A | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs551347418, COSV51853101; called by muse, mutect2, varscan2
- SCN4A | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 122/290 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.096); catalogued as rs369830835, COSV71127154; called by muse, mutect2, varscan2
- SEMA4G | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774063487, COSV52966041; called by muse, mutect2, varscan2
- SEPTIN4 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs772182274, COSV57898217; called by muse, mutect2, varscan2
- SERBP1 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 146/386 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.95); catalogued as rs745628272, COSV100769025; called by muse, mutect2, varscan2
- SERTAD2 | c.698C>T p.T233M | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs755073979, COSV100512047; called by muse, mutect2, varscan2
- SESN3 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV99565124; called by muse, mutect2, varscan2
- SETDB2 | c.1075C>T p.R359* | Nonsense Mutation (SNP) | VAF 78/212 reads (37%) | catalogued as rs752831641, COSV99320406; called by muse, mutect2, varscan2
- SEZ6L2 | c.1270G>A p.D424N (on ENST00000308713 / NM_001114099.3; = p.D354N on NM_012410.4) | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (1); PolyPhen possibly damaging (0.468); catalogued as rs547134098, COSV58104129; called by muse, mutect2, varscan2
- SFRP1 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55174909, COSV55176505; called by muse, mutect2, varscan2
- SGSM2 | c.1654-2A>G p.X552_splice (on ENST00000426855 / NM_001098509.2; = p.X597_splice on NM_014853.3) | Splice Site (SNP) | VAF 32/88 reads (36%) | catalogued as COSV99279559; called by muse, mutect2, varscan2
- SH3RF3 | c.1859G>A p.R620Q | Missense Mutation (SNP) | VAF 197/451 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs376984287; called by muse, mutect2, varscan2
- SHANK1 | c.2644C>T p.P882S | Missense Mutation (SNP) | VAF 81/195 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV99519800; called by muse, mutect2, varscan2
- SIDT2 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 83/226 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.22); catalogued as rs956801595, COSV54060789; called by muse, mutect2, varscan2
- SIGLEC1 | c.2324G>A p.R775H | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs564843501, COSV52460473; called by muse, mutect2, varscan2
- SIGLEC10 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 158/402 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs754521676, COSV100218334; called by muse, mutect2, varscan2
- SIPA1 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 60/141 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as rs374792529; called by muse, varscan2
- SIPA1L3 | c.290G>A p.S97N | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99726750; called by muse, mutect2, varscan2
- SIRT2 | c.568T>G p.F190V | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99979094; called by muse, mutect2, varscan2
- SLC12A1 | c.2628del p.D877Mfs*46 | Frame Shift Del (DEL) | VAF 25/158 reads (16%) | catalogued as rs1419151341, COSV66797187; called by mutect2, pindel, varscan2
- SLC16A1 | c.825del p.F275Lfs*37 | Frame Shift Del (DEL) | VAF 87/236 reads (37%) | catalogued as rs150151185; called by mutect2, pindel, varscan2
- SLC16A1 | c.524G>A p.R175K | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.447); catalogued as COSV100855740; called by muse, mutect2, varscan2
- SLC16A7 | c.786del p.F262Lfs*39 | Frame Shift Del (DEL) | VAF 69/271 reads (25%) | catalogued as COSV53899988; called by mutect2, pindel, varscan2
- SLC1A1 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 88/232 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as rs199857691, COSV99261015; called by muse, varscan2
- SLC20A2 | c.1510G>A p.G504S | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as COSV100645951, COSV60604884; called by muse, mutect2, varscan2
- SLC22A6 | c.991C>T p.R331C | Missense Mutation (SNP) | VAF 68/147 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150409056, COSV64561181; called by muse, mutect2, varscan2
- SLC25A6 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 93/211 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.331); catalogued as rs1369618113, COSV101195390; called by muse, mutect2, varscan2
- SLC2A14 | c.1327C>T p.L443F | Missense Mutation (SNP) | VAF 207/358 reads (58%) | SIFT tolerated (0.3); PolyPhen benign (0.033); catalogued as COSV100533372; called by muse, mutect2, varscan2
- SLC35F5 | c.143T>C p.V48A | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.023); catalogued as COSV99829873; called by muse, mutect2, varscan2
- SLC37A2 | c.971A>G p.N324S | Missense Mutation (SNP) | VAF 97/199 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.065); catalogued as rs773920448, COSV100016808; called by muse, mutect2, varscan2
- SLC39A7 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1202409452, COSV63002249; called by muse, mutect2, varscan2
- SLC41A3 | c.1034G>A p.S345N | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV100259219; called by muse, mutect2, varscan2
- SLC4A2 | c.1784G>A p.R595Q | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as rs761077150, COSV59656111; called by muse, mutect2, varscan2
- SLC6A13 | c.1063C>A p.P355T | Missense Mutation (SNP) | VAF 41/398 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1446181233, COSV100569644, COSV58255447; called by muse, mutect2
- SLC6A3 | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.747); catalogued as rs150576860; called by muse, mutect2, varscan2
- SLC8A3 | c.1396G>A p.V466M | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as rs755672807, COSV100775783; called by muse, mutect2, varscan2
- SLF2 | c.572G>A p.G191D | Missense Mutation (SNP) | VAF 71/180 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV99488196; called by muse, mutect2, varscan2
- SLF2 | c.1106A>T p.H369L | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as COSV99488204; called by muse, mutect2, varscan2
- SLPI | c.306del p.N103Ifs*13 | Frame Shift Del (DEL) | VAF 40/101 reads (40%) | catalogued as rs745834619; called by mutect2, pindel, varscan2
- SMC2 | c.2251del p.T751Pfs*9 | Frame Shift Del (DEL) | VAF 69/210 reads (33%) | catalogued as rs1257129093; called by mutect2, pindel, varscan2
- SMCHD1 | c.2040del p.K680Nfs*3 | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | catalogued as rs766211852; called by mutect2, varscan2
- SNRNP200 | c.3689G>T p.S1230I | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100106750; called by muse, mutect2, varscan2
- SNRNP35 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 42/63 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781256349, COSV100644527; called by muse, mutect2, varscan2
- SNRPA | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as rs750727750, COSV99698674; called by muse, mutect2
- SNX1 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99975774; called by muse, mutect2, varscan2
- SNX20 | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 44/88 reads (50%) | catalogued as rs199531677, COSV100319303; called by muse, mutect2, varscan2
- SOHLH2 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764959799, COSV65901489, COSV65904110; called by muse, mutect2, varscan2
- SORBS1 | c.3466G>A p.V1156M | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); catalogued as rs772386830, COSV53367631; called by muse, mutect2, varscan2
- SOX10 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 82/188 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62806470, COSV62807596; called by muse, mutect2, varscan2
- SPAG16 | c.335T>G p.F112C | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99793237; called by muse, mutect2, varscan2
- SPAG17 | c.282del p.K94Nfs*3 | Frame Shift Del (DEL) | VAF 66/348 reads (19%) | catalogued as rs771461785; called by mutect2, pindel, varscan2
- SPATA20 | c.971G>A p.R324H (on ENST00000356488 / NM_001258372.1; = p.R340H on NM_022827.4) | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.233); catalogued as rs368022155; called by muse, mutect2, varscan2
- SPATA9 | c.434C>T p.T145I | Missense Mutation (SNP) | VAF 151/396 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV99174118; called by muse, mutect2, varscan2
- SPG21 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs756437687, COSV99200174; called by muse, mutect2, varscan2
- SPHK2 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 83/168 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.27); catalogued as rs11544355, COSV55335982; called by muse, mutect2, varscan2
- SPI1 | c.297del p.M100Wfs*86 | Frame Shift Del (DEL) | VAF 22/61 reads (36%) | catalogued as rs1265596655, COSV99908809; called by mutect2, pindel, varscan2
- SPPL2C | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.806); catalogued as rs774363885, COSV61291952; called by muse, mutect2, varscan2
- SPTB | c.6880C>T p.R2294C | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.39); catalogued as rs770384233, COSV99906093; called by muse, mutect2, varscan2
- SPTBN2 | c.5341G>A p.E1781K | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777756110, COSV100017840; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPTBN5 | c.9520C>T p.R3174W | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs780341578, COSV100310308; called by muse, mutect2, varscan2
- SRP68 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 133/293 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs746905444, COSV57164854; called by muse, mutect2, varscan2
- SRPK1 | c.1197C>A p.S399R | Missense Mutation (SNP) | VAF 127/312 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV100644212; called by muse, mutect2, varscan2
657 further variants in this file (306 protein-altering or splice-affecting, 333 silent, 18 other) are not listed here.
